Surgical pathology report (de-identified scan), TCGA case TCGA-CM-4744, project TCGA-COAD (Colon Adenocarcinoma), tissue source site MSKCC, specimen TCGA-CM-4744-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

....

Clinical Diagnosis & History:

year old male with history of colon carcinoma.

Specimens Submitted:

1: terminal ileum, appendix, and ascending colon; Right hemicolectomy

DIAGNOSIS:

1. TERMINAL ILEUM, APPENDIX, AND ASCENDING COLON; RIGHT
HEMICOLECTOMY:

- TUMOR TYPE: ADENOCARCINOMA.
- HISTOLOGIC GRADE: MODERATELY DIFFERENTIATED.
- TUMOR LOCATION: CECUM.
- TUMOR SIZE:
- LENGTH IS 4.5 CM
- WIDTH IS 4.0 CM
- MAXIMAL THICKNESS IS 0.5 CM
- PREEXISTING POLYP (AT THE SITE OF THE CARCINOMA): TUBULOVILLOUS

ADENOMA

- TUMOR INVASION: INVASION INTO MUSCULARIS PROPRIA.
- SEROSAL INVOLVEMENT: NOT IDENTIFIED.
- VASCULAR INVASION: IDENTIFIED.
- PERINEURAL INVASION: NOT IDENTIFIED.
- SURGICAL MARGINS : FREE OF TUMOR.
- POLYPS (AWAY FROM THE CARCINOMA): NOT IDENTIFIED.
- NON-NEOPLASTIC BOWEL: UNREMARKABLE.
- THE PATHOLOGIC STAGE IS (AJCC) pT2.
- LYMPH NODES: TWENTY-EIGHT BENIGN LYMPH NODES (0/28)
- THE PATHOLOGIC STAGE IS (AJCC) : pN0.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF
THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED
THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

** Continued on next page **

[page 2 of 2]
1. The specimen is received fresh, labeled "Right hemicolectomy" and consists of a segment of terminal ileum, cecum with attached appendix and ascending colon. The terminal ileum measures 9.0 cm in length and 4.5 cm in circumference at the proximal resected margin. The remaining colon measures 18.5 cm in length with a circumference of 8.3 cm at the distal resected margin. The attached appendix measures 6.0 cm in length and averages 0.5 cm in diameter. The appendiceal and intestinal serosa is pink tan and smooth. Focally hemorrhagic lobulated yellow tan adipose tissue spans the length of the specimen measuring up to 4.0 cm in thickness. The specimen is opened to reveal a mass lesion in the cecum, 0.5 cm distal to the ileocecal valve, measuring 4.5 cm in length and 4.0 cm in width. Sectioning show that the tumor invades into the muscle wall. The depth of invasion is 0.5 cm grossly. The remaining mucosa is unremarkable. The specimen is submitted for lymph node dissection. Multiple lymph nodes are identified in the attached adipose tissue and are submitted. Representative sections of the specimen are submitted for permanent sections and for TPS.

Summary of sections:

P-- proximal margin shave
D -- distal margin shave
M-- mass
A -- appendix representative sections
RS--representative sections
BLN -- bisected lymph nodes
LN-- lymph nodes

Summary of Sections:

Part 1: terminal ileum, appendix, and ascending colon; Right hemicolectomy

Block	Sect. Site	FCs
1	AP	3
2	BLN	4
1	DM	1
6	LN	22
1	PM	1
1	RS	1
6	T	6

** End of Report **

Source: NCI Genomic Data Commons file 358b22ad-f04d-4ad7-8b94-8ca952644230 (TCGA-CM-4744.1428CD76-93D4-4E03-AD3C-DDB9166FA39C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).